Somatic mutation profile of tumor specimen TCGA-DK-AA6R-01A (aliquot TCGA-DK-AA6R-01A-11D-A42E-08) from TCGA case TCGA-DK-AA6R, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Lateral wall of bladder; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Age at diagnosis: 69.0 years (25,196 days).
Specimen TCGA-DK-AA6R-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) dbb681d2-2279-4c30-a99e-9541259e0b89.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DK-AA6R-10A (Blood Derived Normal), aliquot TCGA-DK-AA6R-10A-01D-A42H-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3f55fcf5-997d-4734-80fb-3091055787ef

The open-access MAF lists 379 somatic variants for this specimen: 292 protein-altering or splice-affecting, 77 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 250, Silent 77, Nonsense Mutation 22, Splice Site 9, Frame Shift Del 6, Intron 6, Splice Region 2, 3'UTR 2, In Frame Ins 1, Translation Start Site 1, RNA 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CHD7 | c.604C>T p.Q202* | Nonsense Mutation (SNP) | VAF 10/34 reads (29%) | catalogued as rs1554581277, CM126592, COSV101418413; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 25/40 reads (63%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs11540652, CM920675, COSV52661091, COSV52661580, COSV52675468, COSV52802300; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCA3 | c.1645G>T p.V549F | Missense Mutation (SNP) | VAF 55/83 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV57053387; called by muse, mutect2, varscan2
- ABCA6 | c.3652G>T p.E1218* | Nonsense Mutation (SNP) | VAF 6/47 reads (13%) | catalogued as COSV99446217; called by muse, mutect2, varscan2
- ABCA6 | c.3651G>T p.M1217I | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.041); catalogued as rs1296029373, COSV52638470, COSV52639502; called by muse, mutect2
- ABCA9 | c.3394G>C p.G1132R | Missense Mutation (SNP) | VAF 17/99 reads (17%) | SIFT tolerated (0.35); PolyPhen benign (0.044); catalogued as rs1372459946, COSV60624613; called by muse, mutect2, varscan2
- ABCC5 | c.1615C>T p.Q539* | Nonsense Mutation (SNP) | VAF 22/74 reads (30%) | catalogued as COSV99657513; called by muse, varscan2
- ABCC5 | c.1429C>T p.H477Y | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs761768094, COSV55589919; called by muse, varscan2
- ABCE1 | c.1138G>A p.E380K | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.598); catalogued as rs1485295098, COSV56847103; called by muse, mutect2, varscan2
- ABCG2 | c.452C>A p.T151N | Missense Mutation (SNP) | VAF 25/129 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.71); catalogued as COSV52945918; called by muse, mutect2, varscan2
- ABRAXAS2 | c.530C>A p.S177* | Nonsense Mutation (SNP) | VAF 14/47 reads (30%) | catalogued as COSV100045106; called by muse, mutect2, varscan2
- AC131160.1 | c.949G>T p.A317S | Missense Mutation (SNP) | VAF 14/98 reads (14%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.908); catalogued as COSV57700637; called by muse, mutect2, varscan2
- ADAM15 | c.1543G>A p.G515R | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.993); catalogued as rs1056634306, COSV55126806; called by muse, mutect2, varscan2
- ADAMTS15 | c.699C>A p.F233L | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.886); catalogued as COSV100143746; called by muse, mutect2
- ADARB1 | c.2098G>A p.E700K (on ENST00000360697 / NM_001346687.2; = p.E660K on NM_001112.4) | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.491); catalogued as COSV62342089, COSV62344188; called by muse, mutect2
- ADCY5 | c.2559G>A p.M853I | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT tolerated (0.16); PolyPhen benign (0.009); catalogued as COSV59197580; called by muse, mutect2, varscan2
- AGAP6 | c.365G>T p.C122F (on ENST00000374056 / NM_001365867.1; = p.C145F on NM_001077665.2) | Missense Mutation (SNP) | VAF 37/1049 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.012); catalogued as COSV65017658; called by muse, mutect2
- AHNAK2 | c.10569T>G p.I3523M | Missense Mutation (SNP) | VAF 34/217 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.392); catalogued as COSV60914957; called by muse, mutect2, varscan2
- AK7 | c.418G>T p.V140F | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.052); catalogued as COSV50871520; called by muse, mutect2, varscan2
- AK9 | c.323G>A p.C108Y | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.314); catalogued as rs1166732065, COSV53421194; called by muse, mutect2, varscan2
- ALDH8A1 | c.730G>T p.A244S | Missense Mutation (SNP) | VAF 19/29 reads (66%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.955); catalogued as COSV55640284, COSV55641714; called by muse, mutect2, varscan2
- ANKRD7 | c.148T>C p.Y50H | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs896290597, COSV54554721; called by muse, mutect2, varscan2
- ANKS4B | c.7A>T p.T3S | Missense Mutation (SNP) | VAF 53/299 reads (18%) | SIFT tolerated (0.58); PolyPhen benign (0.014); catalogued as COSV61139178; called by muse, mutect2, varscan2
- ANKZF1 | c.452T>G p.F151C | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV55476516; called by mutect2, varscan2
- AP2B1 | c.817G>A p.D273N | Missense Mutation (SNP) | VAF 24/176 reads (14%) | SIFT tolerated (0.4); PolyPhen benign (0.012); catalogued as COSV51999299; called by muse, mutect2, varscan2
- ARHGAP33 | c.2654G>A p.G885E | Missense Mutation (SNP) | VAF 23/42 reads (55%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.055); catalogued as rs1465162478, COSV50123079; called by muse, mutect2, varscan2
- ARID1A | c.3254C>G p.S1085* | Nonsense Mutation (SNP) | VAF 8/26 reads (31%) | catalogued as COSV100249938, COSV61383854; called by muse, mutect2, varscan2
- ARID4B | c.1510G>C p.D504H | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.146); catalogued as COSV51602930; called by muse, mutect2, varscan2
- ASTN2 | c.868C>A p.L290M | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV57776061; called by muse, mutect2, varscan2
- ATP2C1 | c.2396G>T p.R799L | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.112); catalogued as rs1255158711, COSV60756168; called by muse, mutect2, varscan2
- BAIAP2 | c.1472A>G p.Y491C | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.905); catalogued as COSV100348795; called by muse, mutect2
- BCAM | c.712G>C p.A238P | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.531); catalogued as COSV54302202; called by muse, mutect2, varscan2
- BIRC6 | c.10510A>G p.S3504G | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.66); catalogued as COSV70199062; called by muse, mutect2, varscan2
- BMP7 | c.951C>A p.N317K | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV67780691; called by muse, mutect2, varscan2
- C1RL | c.535G>A p.E179K | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.47); PolyPhen benign (0.001); catalogued as COSV56924931; called by muse, mutect2, varscan2
- C2orf16 | c.4199G>A p.C1400Y | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT tolerated (0.83); PolyPhen benign (0.003); catalogued as COSV62675460; called by muse, mutect2, varscan2
- CACTIN | c.895C>T p.R299C | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1382651018, COSV50268011, COSV50275482; called by muse, mutect2
- CACUL1 | c.943C>T p.P315S | Missense Mutation (SNP) | VAF 36/142 reads (25%) | SIFT tolerated (0.26); PolyPhen benign (0.356); catalogued as rs774818489, COSV60994281; called by muse, mutect2, varscan2
- CAMKV | c.682G>A p.D228N | Missense Mutation (SNP) | VAF 38/104 reads (37%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.044); catalogued as COSV56555338, COSV56555401; called by muse, mutect2, varscan2
- CARD6 | c.1048C>A p.L350M | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.459); catalogued as COSV54566138; called by muse, mutect2, varscan2
- CASKIN1 | c.1535C>G p.T512R | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58872468; called by muse, mutect2, varscan2
- CC2D2B | c.290T>C p.I97T | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV60357901; called by muse, mutect2, varscan2
- CCR5 | c.167T>C p.I56T | Missense Mutation (SNP) | VAF 30/115 reads (26%) | SIFT tolerated (0.48); PolyPhen benign (0.145); catalogued as COSV52751597; called by muse, mutect2, varscan2
- CD2AP | c.1696C>G p.P566A | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.018); catalogued as COSV63760727; called by muse, mutect2, varscan2
- CEP20 | c.404C>T p.S135L | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs757411696, COSV55383771; called by muse, mutect2, varscan2
- CFAP43 | c.3800G>T p.R1267I | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.648); catalogued as COSV63853064, COSV63853310; called by muse, mutect2, varscan2
- CFAP52 | c.460G>T p.A154S | Missense Mutation (SNP) | VAF 6/100 reads (6%) | SIFT tolerated (0.89); PolyPhen benign (0.038); catalogued as COSV100235636, COSV55344774; called by muse, mutect2
- CFAP58 | c.2581G>A p.G861S | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV63832396, COSV63834047; called by muse, mutect2, varscan2
- CFAP65 | c.330G>A p.M110I (on ENST00000341552 / NM_194302.4; = p.M45I on NM_152389.4) | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.027); catalogued as COSV55390283; called by muse, mutect2, varscan2
- CFAP77 | c.564G>T p.Q188H | Missense Mutation (SNP) | VAF 19/86 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.092); catalogued as COSV58010734; called by muse, mutect2
- CFAP77 | c.565G>T p.D189Y | Missense Mutation (SNP) | VAF 18/85 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.173); catalogued as COSV58010747; called by muse, mutect2, varscan2
- CGA | c.94C>G p.P32A | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.905); catalogued as COSV63644400; called by muse, mutect2, varscan2
- CLHC1 | c.1335G>T p.Q445H | Missense Mutation (SNP) | VAF 20/79 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.751); catalogued as COSV68464095; called by muse, mutect2, varscan2
- CLK1 | c.230G>A p.R77K | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.481); catalogued as COSV58432255, COSV58433643; called by muse, mutect2, varscan2
- CNGB3 | c.1567G>A p.D523N | Missense Mutation (SNP) | VAF 35/98 reads (36%) | SIFT tolerated (0.28); PolyPhen benign (0.03); catalogued as rs1339909780, COSV60689460; called by muse, mutect2, varscan2
- COL15A1 | c.753G>T p.E251D | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT tolerated (0.2); PolyPhen benign (0.063); catalogued as COSV66644512; called by muse, mutect2, varscan2
- COL5A2 | c.1418C>G p.P473R | Missense Mutation (SNP) | VAF 10/116 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.275); catalogued as COSV66409595; called by muse, mutect2
- COL5A2 | c.1417C>A p.P473T | Missense Mutation (SNP) | VAF 10/118 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.142); catalogued as COSV66409601; called by muse, mutect2
- CPE | c.1108G>A p.E370K | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.021); catalogued as rs1405438270, COSV68580200; called by muse, mutect2, varscan2
- CR1L | c.1007G>A p.G336E | Missense Mutation (SNP) | VAF 26/119 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs182966795, COSV54325130; called by muse, mutect2, varscan2
- CSMD3 | c.8153A>C p.K2718T | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.601); catalogued as COSV52175307; called by muse, mutect2, varscan2
- CUBN | c.9524C>T p.S3175L | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT tolerated (0.8); PolyPhen benign (0.011); catalogued as rs368697251, COSV64711140; called by muse, mutect2, varscan2
- CUL4B | c.2014C>T p.P672S | Missense Mutation (SNP) | VAF 27/77 reads (35%) | SIFT tolerated (0.22); PolyPhen benign (0.038); catalogued as COSV60687285; called by muse, mutect2, varscan2
- CUL7 | c.2725G>T p.G909W | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM053192, COSV54816737, COSV99538792; called by muse, mutect2, varscan2
- CYB5RL | c.34G>A p.E12K | Missense Mutation (SNP) | VAF 63/115 reads (55%) | SIFT tolerated (0.1); PolyPhen benign (0.211); catalogued as COSV55277349; called by muse, mutect2, varscan2
- CYP7A1 | c.814G>T p.D272Y | Missense Mutation (SNP) | VAF 16/145 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV56963436; called by muse, mutect2, varscan2
- DCDC1 | c.4819G>T p.V1607L (on ENST00000597505 / NM_001367979.1; = p.V714L on NM_020869.3) | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.049); catalogued as rs376659024, COSV57999140; called by muse, mutect2, varscan2
- DDI1 | c.890G>C p.R297T | Missense Mutation (SNP) | VAF 23/42 reads (55%) | SIFT tolerated (0.09); PolyPhen benign (0.291); catalogued as COSV56377570, COSV56385893; called by muse, mutect2, varscan2
- DDIT4 | c.95C>T p.S32L | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated (0.37); PolyPhen benign (0.107); catalogued as COSV56577136; called by muse, mutect2, varscan2
- DDX42 | c.238G>A p.E80K | Missense Mutation (SNP) | VAF 31/99 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.453); catalogued as COSV63790087; called by muse, mutect2, varscan2
- DENND4C | c.2084C>T p.P695L | Missense Mutation (SNP) | VAF 42/88 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.031); catalogued as rs755954360, COSV66822092; called by muse, mutect2, varscan2
- DGKG | c.1382C>A p.P461H | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53964931; called by muse, varscan2
- DGKG | c.1381C>A p.P461T | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53964940; called by muse, varscan2
- DGKG | c.1367A>G p.H456R | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.036); catalogued as rs369559729; called by muse, varscan2
- DLEC1 | c.1102G>T p.D368Y | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.407); catalogued as rs1452242079, COSV57299504; called by muse, mutect2, varscan2
- DLL3 | c.922C>T p.R308W | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.636); catalogued as rs1431230159, COSV52694604; called by muse, mutect2, varscan2
- DNASE2 | c.925G>T p.V309L | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.4); catalogued as COSV52246608, COSV99262413, COSV99263955; called by muse, mutect2, varscan2
- DOCK7 | c.2998G>C p.V1000L (on ENST00000635253 / NM_001367561.1; = p.V969L on NM_033407.3) | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.14); catalogued as COSV52004740, COSV99226751; called by muse, mutect2, varscan2
- DSC3 | c.1857C>G p.I619M | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT tolerated (0.28); PolyPhen benign (0.024); catalogued as rs778864804, COSV64572876, COSV64575354; called by muse, mutect2, varscan2
- EIF2S1 | c.415G>A p.D139N | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.827); catalogued as COSV56452340, COSV56452992; called by muse, mutect2, varscan2
- EIF4E2 | c.271-1G>A p.X91_splice | Splice Site (SNP) | VAF 4/9 reads (44%) | catalogued as COSV51471695, COSV99299308; called by muse, mutect2
- EIF4G3 | c.3545G>T p.G1182V | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.706); catalogued as COSV51681519; called by muse, mutect2, varscan2
- EIF4G3 | c.3544G>T p.G1182* | Nonsense Mutation (SNP) | VAF 20/72 reads (28%) | catalogued as COSV99945482; called by muse, mutect2, varscan2
- ELMO1 | c.1672G>A p.E558K | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.031); catalogued as COSV60304005; called by muse, mutect2, varscan2
- ENPP7 | c.763C>T p.R255W | Missense Mutation (SNP) | VAF 37/72 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.241); catalogued as rs144546446; called by muse, mutect2, varscan2
- EPHB3 | c.977G>A p.R326H | Missense Mutation (SNP) | VAF 28/125 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as rs1389820335, COSV57805846; called by muse, mutect2, varscan2
- EPS15L1 | c.1336C>G p.Q446E | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.603); catalogued as COSV50168623; called by muse, mutect2, varscan2
- ERCC3 | c.2291C>T p.S764L | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.023); catalogued as rs189511674, COSV53425649; called by muse, mutect2, varscan2
- EYA2 | c.895A>G p.T299A | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT tolerated (0.49); PolyPhen benign (0.013); catalogued as COSV57942804; called by muse, mutect2, varscan2
- FAM135B | c.2223C>G p.S741R | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52723444; called by muse, mutect2, varscan2
- FAM193A | c.1210G>A p.E404K | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.54); catalogued as rs1205350542, COSV61193832; called by muse, mutect2, varscan2
- FBXO45 | c.852_853del p.D285Rfs*8 | Frame Shift Del (DEL) | VAF 8/32 reads (25%) | catalogued as COSV61146486; called by mutect2, pindel
- FDPS | c.112G>T p.G38W | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.009); catalogued as rs974743669, COSV100756273; called by muse, mutect2
- FEM1A | c.938G>C p.R313P | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54163783; called by muse, mutect2, varscan2
- FGF14 | c.208G>A p.G70S | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV65943169; called by muse, mutect2, varscan2
- FGF7 | c.82A>G p.I28V | Missense Mutation (SNP) | VAF 43/96 reads (45%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs757572324, COSV51066070; called by muse, mutect2, varscan2
- FH | c.939A>T p.E313D | Missense Mutation (SNP) | VAF 17/31 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CD112090, COSV63818143; called by muse, mutect2, varscan2
- FRAS1 | c.11382C>A p.F3794L | Missense Mutation (SNP) | VAF 22/136 reads (16%) | SIFT tolerated (0.26); PolyPhen benign (0.034); catalogued as COSV53608983; called by muse, mutect2, varscan2
- FRAS1 | c.11383C>A p.H3795N | Missense Mutation (SNP) | VAF 21/133 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.165); catalogued as COSV53608999; called by muse, mutect2, varscan2
- FSIP2 | c.16306G>A p.E5436K | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT tolerated (0.15); PolyPhen benign (0.14); catalogued as COSV58085231; called by muse, mutect2, varscan2
- FSIP2 | c.16912C>A p.L5638I | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV58085247; called by muse, mutect2, varscan2
- FYN | c.986T>C p.L329P | Missense Mutation (SNP) | VAF 25/44 reads (57%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV57614021; called by muse, mutect2, varscan2
- GABRQ | c.694C>A p.Q232K | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.146); catalogued as COSV64781912; called by muse, mutect2, varscan2
- GALNT1 | c.940G>C p.D314H | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as rs1170941065, COSV52452205; called by muse, mutect2, varscan2
- GAS8 | c.37A>C p.K13Q | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.84); catalogued as COSV51943520; called by muse, mutect2, varscan2
- GCKR | c.286G>A p.E96K | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.018); catalogued as rs757929029, COSV53021162; called by muse, mutect2, varscan2
- GGCX | c.170G>T p.R57L | Missense Mutation (SNP) | VAF 27/136 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.116); catalogued as COSV52088253; called by muse, mutect2, varscan2
- GIMAP5 | c.803C>T p.A268V | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT tolerated (0.77); PolyPhen benign (0.007); catalogued as rs1252099291, COSV57529967; called by muse, mutect2, varscan2
- GNB1L | c.979G>T p.A327S | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV100284037, COSV61548470; called by muse, mutect2, varscan2
- GNPDA2 | c.23A>T p.N8I | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.089); catalogued as COSV54946673; called by muse, mutect2, varscan2
- GPR176 | c.1022G>A p.R341Q | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.895); catalogued as rs778260626, COSV54444973; called by muse, mutect2
- GPR50 | c.30del p.Y11Mfs*17 | Frame Shift Del (DEL) | VAF 8/46 reads (17%) | catalogued as rs1412998291, COSV54437405; called by pindel, varscan2
- GRIK5 | c.2267C>T p.S756F | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV53478363; called by muse, mutect2, varscan2
- GYS1 | c.91G>C p.E31Q | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54402747; called by muse, mutect2, varscan2
- H2AC11 | c.13G>T p.G5C | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.945); catalogued as COSV60362113; called by muse, mutect2, varscan2
- H2AC11 | c.14G>T p.G5V | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.954); catalogued as COSV60362118, COSV60362221; called by muse, mutect2, varscan2
- HACL1 | c.124G>A p.E42K | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57729087; called by muse, mutect2, varscan2
- HAUS5 | c.766G>A p.A256T | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT tolerated (0.52); PolyPhen benign (0.178); catalogued as COSV52547835; called by muse, mutect2, varscan2
- HECTD4 | c.7327G>A p.E2443K | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV66391795; called by muse, mutect2, varscan2
- HERC1 | c.12388G>T p.A4130S | Missense Mutation (SNP) | VAF 43/273 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs766264015, COSV71247742; called by muse, mutect2, varscan2
- HINFP | c.1451C>G p.S484C | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.241); catalogued as rs1055059734, COSV63431999; called by muse, mutect2, varscan2
- HPS3 | c.1576C>T p.H526Y | Missense Mutation (SNP) | VAF 19/96 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56054280; called by muse, mutect2, varscan2
- HRNR | c.1679C>A p.P560Q | Missense Mutation (SNP) | VAF 35/201 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV64257716; called by muse, mutect2, varscan2
- HSPA5 | c.1936G>C p.E646Q | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.031); catalogued as COSV52335339; called by muse, mutect2, varscan2
- HTR7 | c.892G>T p.E298* | Nonsense Mutation (SNP) | VAF 3/14 reads (21%) | catalogued as COSV53291580; called by muse, mutect2
- HTR7 | c.891G>C p.K297N | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.551); catalogued as COSV53286390, COSV53291599; called by muse, mutect2
- IGF2 | c.565C>G p.L189V (on ENST00000434045 / NM_001127598.3; = p.L133V on NM_000612.6) | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.441); catalogued as rs530101369, COSV100323982, COSV56098721; called by muse, mutect2, varscan2
- IGKV1-16 | c.257G>C p.G86A | Missense Mutation (SNP) | VAF 36/201 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.762); catalogued as rs766683552; called by muse, mutect2, varscan2
- IGKV3D-11 | c.86C>T p.A29V | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.176); catalogued as rs761599298; called by muse, mutect2, varscan2
- IGKV6D-41 | c.148G>A p.G50S | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs775114758; called by muse, mutect2, varscan2
- IL20RA | c.625G>T p.E209* | Nonsense Mutation (SNP) | VAF 15/37 reads (41%) | catalogued as COSV100360212; called by muse, mutect2, varscan2
- INF2 | c.1925A>G p.N642S | Missense Mutation (SNP) | VAF 13/104 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs750902388, COSV53032435; called by muse, mutect2, varscan2
- JMJD1C | c.2712G>T p.W904C | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1178386424, COSV59514695; called by muse, mutect2
- KAZN | c.398G>C p.R133T | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.977); catalogued as COSV100748084; called by muse, mutect2
- KCNK18 | c.295A>G p.T99A | Missense Mutation (SNP) | VAF 23/116 reads (20%) | SIFT tolerated (0.88); PolyPhen benign (0.001); catalogued as COSV57971738; called by muse, mutect2, varscan2
- KCNK5 | c.1283G>T p.G428V | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated (0.56); PolyPhen benign (0.073); catalogued as COSV63988876; called by muse, mutect2, varscan2
- KCNK5 | c.1282G>A p.G428S | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated (0.56); PolyPhen benign (0.001); catalogued as COSV63988877; called by muse, mutect2, varscan2
- KCNQ2 | c.1379C>A p.A460D (on ENST00000359125 / NM_172107.4; = p.A432D on NM_004518.6) | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.036); catalogued as COSV60544539; called by muse, mutect2, varscan2
- KCTD17 | c.356C>T p.P119L | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.65); catalogued as COSV100786766, COSV63248929; called by muse, mutect2, varscan2
- KHDRBS1 | c.992G>A p.R331Q | Missense Mutation (SNP) | VAF 31/89 reads (35%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs1294530012, COSV56981911, COSV56984119; called by muse, mutect2, varscan2
- KIF15 | c.34G>T p.V12L | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.022); catalogued as COSV58160448; called by muse, mutect2, varscan2
- KRT76 | c.395G>T p.G132V | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (0.4); PolyPhen benign (0.005); catalogued as COSV60120197; called by muse, mutect2, varscan2
- L1CAM | c.1411G>T p.D471Y | Missense Mutation (SNP) | VAF 22/41 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as COSV62828024; called by muse, mutect2, varscan2
- L1CAM | c.1410G>T p.Q470H | Missense Mutation (SNP) | VAF 22/41 reads (54%) | SIFT tolerated (0.08); PolyPhen benign (0.031); catalogued as COSV62828027; called by muse, mutect2, varscan2
- LAMB3 | c.1979G>A p.R660Q | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs375951428; called by muse, mutect2, varscan2
- LRIG1 | c.2578G>A p.E860K | Missense Mutation (SNP) | VAF 29/48 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs750912449, COSV56239864; called by muse, mutect2, varscan2
- LRRC8E | c.1711C>G p.R571G | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.414); catalogued as COSV60717559, COSV60718056; called by muse, mutect2, varscan2
- LRRK2 | c.343C>T p.H115Y | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.56); catalogued as COSV54145232; called by muse, mutect2, varscan2
- MACF1 | c.12689C>G p.S4230C (on ENST00000372915; = p.S2163C on NM_012090.5) | Missense Mutation (SNP) | VAF 46/103 reads (45%) | catalogued as COSV57120326; called by muse, mutect2, varscan2
- MAGEB18 | c.10G>T p.G4C | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57463947, COSV57464433; called by muse, mutect2, varscan2
- MRPL47 | c.646C>T p.R216* | Nonsense Mutation (SNP) | VAF 12/100 reads (12%) | catalogued as rs1470879065, COSV99373053; called by muse, mutect2, varscan2
- MUC5B | c.6773G>A p.S2258N | Missense Mutation (SNP) | VAF 32/118 reads (27%) | SIFT tolerated (0.36); PolyPhen benign (0.418); catalogued as COSV71591998; called by muse, mutect2, varscan2
- MYO18B | c.6356C>A p.S2119Y | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.804); catalogued as COSV59133904; called by muse, mutect2, varscan2
- MYO3A | c.2377G>C p.E793Q | Missense Mutation (SNP) | VAF 52/101 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56330071, COSV56331193; called by muse, mutect2, varscan2
- MYO3B | c.1873C>G p.Q625E | Missense Mutation (SNP) | VAF 12/93 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.224); catalogued as COSV58702686; called by muse, mutect2, varscan2
- NCALD | c.76G>T p.E26* | Nonsense Mutation (SNP) | VAF 29/150 reads (19%) | catalogued as COSV99636739, COSV99637677; called by muse, mutect2, varscan2
- NCOA2 | c.797C>T p.S266L | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.155); catalogued as COSV71763953; called by muse, mutect2, varscan2
- NECTIN2 | c.142G>T p.G48C | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.887); catalogued as COSV52977285; called by muse, mutect2
- NKG7 | c.88G>C p.E30Q | Missense Mutation (SNP) | VAF 61/99 reads (62%) | SIFT deleterious (0.03); PolyPhen benign (0.227); catalogued as COSV52467457; called by muse, mutect2, varscan2
- NLRP3 | c.1431C>G p.N477K | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT tolerated (0.2); PolyPhen benign (0.024); catalogued as CM056564, COSV60224027; called by muse, mutect2, varscan2
- NRDE2 | c.481G>C p.E161Q | Missense Mutation (SNP) | VAF 29/158 reads (18%) | SIFT tolerated (0.33); PolyPhen benign (0.01); catalogued as COSV62962182, COSV62963139; called by muse, mutect2, varscan2
- NUP205 | c.5463G>C p.Q1821H | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.359); catalogued as COSV53658912; called by muse, mutect2, varscan2
- ODAPH | c.77A>G p.E26G | Missense Mutation (SNP) | VAF 14/95 reads (15%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0); catalogued as COSV61141195; called by muse, mutect2, varscan2
- ODF2 | c.32G>A p.R11K | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT tolerated, low confidence (1); PolyPhen possibly damaging (0.567); catalogued as COSV63546946; called by muse, mutect2, varscan2
- ODF2 | c.32+1G>T p.X11_splice | Splice Site (SNP) | VAF 17/73 reads (23%) | catalogued as rs755966189, COSV63546950; called by muse, mutect2, varscan2
- OGDHL | c.693G>A p.M231I | Missense Mutation (SNP) | VAF 24/322 reads (7%) | SIFT tolerated (0.17); PolyPhen benign (0.017); catalogued as rs760313650, COSV100934229, COSV65102293; called by muse, mutect2
- OLFM1 | c.369G>C p.E123D (on ENST00000371793 / NM_001282611.2; = p.E105D on NM_006334.4) | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (0.38); PolyPhen benign (0.13); catalogued as COSV52962249; called by muse, mutect2, varscan2
- OR11A1 | c.320C>G p.S107C | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.23); PolyPhen benign (0.135); catalogued as COSV65820950; called by muse, mutect2, varscan2
- OR2T6 | c.172C>A p.P58T | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs775649803, COSV63216213; called by muse, mutect2, varscan2
- OR4K14 | c.928C>T p.Q310* | Nonsense Mutation (SNP) | VAF 50/105 reads (48%) | catalogued as rs149149480, COSV100520383, COSV59292571; called by muse, mutect2, varscan2
- OR4S1 | c.888G>C p.M296I | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.26); PolyPhen benign (0.045); catalogued as COSV60679088; called by muse, mutect2, varscan2
- OR8B4 | c.361C>A p.R121S | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.895); catalogued as rs371189371, COSV62069699; called by muse, mutect2, varscan2
- P2RX7 | c.1039G>T p.A347S | Missense Mutation (SNP) | VAF 11/86 reads (13%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.964); catalogued as COSV55855098; called by muse, mutect2, varscan2
- P2RY6 | c.716G>A p.R239H | Missense Mutation (SNP) | VAF 15/87 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.024); catalogued as rs569014304, COSV62936543; called by muse, mutect2, varscan2
- PBRM1 | c.4933G>T p.E1645* (on ENST00000296302 / NM_001366071.2; = p.E1538* on NM_018313.5) | Nonsense Mutation (SNP) | VAF 25/75 reads (33%) | catalogued as COSV99970053; called by muse, mutect2, varscan2
- PCDH19 | c.3223C>G p.L1075V (on ENST00000373034 / NM_001184880.2; = p.L1027V on NM_020766.3) | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0); catalogued as rs1231286431, COSV55262442, COSV55263005, COSV55274047; called by muse, mutect2, varscan2
- PDE4B | c.1627G>A p.V543I | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); catalogued as rs751786702, COSV58474136; called by muse, mutect2, varscan2
- PDZD2 | c.1609C>T p.R537* | Nonsense Mutation (SNP) | VAF 10/60 reads (17%) | catalogued as rs766389561, COSV56856603; called by muse, mutect2, varscan2
- PGM5 | c.1420G>T p.A474S | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT tolerated (0.41); PolyPhen benign (0.066); catalogued as rs782514355, COSV67167602; called by muse, mutect2, varscan2
- PIGO | c.2441G>A p.R814K | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.53); PolyPhen benign (0.038); catalogued as COSV53053604; called by muse, mutect2, varscan2
- PIK3R6 | c.715G>A p.E239K | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as COSV100266326; called by muse, mutect2, varscan2
- PKHD1L1 | c.4355G>C p.G1452A | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.546); catalogued as COSV65742712; called by muse, mutect2, varscan2
- PLCB3 | c.1114G>A p.E372K | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); catalogued as COSV54188347; called by muse, mutect2, varscan2
- PLCH1 | c.4618G>T p.D1540Y (on ENST00000340059 / NM_001130960.2; = p.D1532Y on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 37/103 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58194244, COSV58196586; called by muse, mutect2, varscan2
- PLEKHA6 | c.1981G>T p.G661W | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.816); catalogued as COSV55333412, COSV55340331; called by muse, mutect2, varscan2
- PLEKHA6 | c.1980G>T p.E660D | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.049); catalogued as COSV55333420; called by mutect2, varscan2
- PLXNA2 | c.804C>G p.I268M | Missense Mutation (SNP) | VAF 17/96 reads (18%) | SIFT tolerated (0.31); PolyPhen benign (0.383); catalogued as rs777000677, COSV65440511; called by muse, mutect2, varscan2
- POGLUT1 | c.321-1G>T p.X107_splice | Splice Site (SNP) | VAF 37/122 reads (30%) | catalogued as COSV55156518; called by muse, mutect2, varscan2
- PPP4R3A | c.2165-1G>T p.X722_splice (on ENST00000554943 / NM_001366432.1; = p.X709_splice on NM_001284280.1) | Splice Site (SNP) | VAF 8/67 reads (12%) | catalogued as COSV61504585; called by muse, mutect2
- PRB4 | c.469C>T p.P157S | Missense Mutation (SNP) | VAF 85/187 reads (45%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.014); catalogued as COSV54396829; called by muse, mutect2, varscan2
- PRKCQ | c.1298C>A p.S433Y | Missense Mutation (SNP) | VAF 7/70 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54110907; called by muse, mutect2, varscan2
- PROM2 | c.2429G>T p.R810L | Missense Mutation (SNP) | VAF 22/108 reads (20%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.665); catalogued as COSV58297977; called by muse, mutect2, varscan2
- PRPF19 | c.1311+2T>G p.X437_splice | Splice Site (SNP) | VAF 12/44 reads (27%) | catalogued as COSV57127900; called by muse, mutect2, varscan2
- PSAP | c.557G>T p.R186L | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as COSV101206520; called by muse, mutect2
- PSD2 | c.671G>A p.R224H | Missense Mutation (SNP) | VAF 12/16 reads (75%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs762173979, COSV51199797; called by muse, varscan2
- PSG2 | c.35A>C p.H12P | Missense Mutation (SNP) | VAF 26/113 reads (23%) | SIFT tolerated (0.21); PolyPhen benign (0.005); catalogued as COSV68884577, COSV68884785; called by muse, mutect2, varscan2
- PTK2 | c.2390G>T p.R797L | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.066); catalogued as rs370847963, COSV61785490; called by muse, mutect2, varscan2
- RAPGEF6 | c.2739G>T p.W913C | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57246120; called by muse, mutect2
- RAPGEF6 | c.2738G>T p.W913L | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57246154; called by muse, mutect2
- RASSF8 | c.834A>T p.Q278H | Missense Mutation (SNP) | VAF 21/89 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV51453501; called by muse, mutect2, varscan2
- REM1 | c.423G>A p.L141= | Splice Region (SNP) | VAF 5/12 reads (42%) | catalogued as COSV99147774; called by muse, mutect2, varscan2
- RGS7 | c.808G>C p.D270H | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV58541096; called by muse, mutect2, varscan2
- RNF145 | c.1185T>A p.Y395* (on ENST00000424310 / NM_001199383.2; = p.Y423* on NM_144726.2) | Nonsense Mutation (SNP) | VAF 25/54 reads (46%) | catalogued as COSV99193843; called by muse, mutect2, varscan2
- RP1L1 | c.3330G>T p.R1110S | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs779384018, COSV66754760; called by muse, mutect2, varscan2
- RP1L1 | c.3329G>T p.R1110M | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV66754766; called by muse, mutect2, varscan2
- RREB1 | c.3758G>T p.R1253L | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs775050440, COSV58552830; called by muse, mutect2, varscan2
- RRP9 | c.348+1G>A p.X116_splice | Splice Site (SNP) | VAF 25/88 reads (28%) | catalogued as rs776825150, COSV51754251; called by muse, mutect2, varscan2
- SAMD9L | c.910G>A p.V304I | Missense Mutation (SNP) | VAF 21/128 reads (16%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV59081433; called by muse, mutect2, varscan2
- SEMA3F | c.1588C>T p.Q530* | Nonsense Mutation (SNP) | VAF 24/67 reads (36%) | catalogued as COSV99137897; called by muse, mutect2, varscan2
- SEMA5B | c.661G>A p.E221K | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.593); catalogued as rs1350124234, COSV52097343; called by muse, mutect2
- SF3B3 | c.3103A>G p.T1035A | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV56787400; called by muse, mutect2, varscan2
- SGK2 | c.604G>A p.E202K | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1460299750, COSV58313188; called by muse, mutect2, varscan2
- SHROOM3 | c.251T>C p.L84P | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1380128710, COSV56028779; called by muse, mutect2, varscan2
- SHROOM3 | c.715C>G p.P239A | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.921); catalogued as COSV56028786; called by muse, mutect2, varscan2
- SIGLEC1 | c.1406C>G p.S469C | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV52463604; called by muse, mutect2, varscan2
- SKP2 | c.404C>G p.S135C | Missense Mutation (SNP) | VAF 11/107 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.076); catalogued as COSV57041986, COSV57043166; called by muse, mutect2
- SLC29A2 | c.1328C>T p.S443F | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV60803303, COSV60803918; called by muse, varscan2
- SLC39A2 | c.856G>C p.E286Q | Missense Mutation (SNP) | VAF 20/88 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.122); catalogued as COSV53869530, COSV53871127; called by muse, varscan2
- SLC39A2 | c.929G>C p.*310Sext*11 | Nonstop Mutation (SNP) | VAF 16/79 reads (20%) | catalogued as rs886179576, COSV53870007, COSV53870732; called by muse, varscan2
- SLC5A9 | c.108C>A p.Y36* | Nonsense Mutation (SNP) | VAF 4/17 reads (24%) | catalogued as COSV99361953, COSV99361983; called by muse, mutect2, varscan2
- SLC8A2 | c.1867+1G>T p.X623_splice | Splice Site (SNP) | VAF 8/39 reads (21%) | catalogued as COSV52639686; called by muse, mutect2, varscan2
- SLFN11 | c.1861C>T p.H621Y | Missense Mutation (SNP) | VAF 31/80 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as COSV100390981; called by muse, mutect2, varscan2
- SLX4IP | c.52G>T p.D18Y | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57946608; called by muse, mutect2, varscan2
- SMG1 | c.5587G>T p.G1863C | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67171200; called by muse, mutect2, varscan2
- SNRPA | c.272C>G p.S91* | Nonsense Mutation (SNP) | VAF 12/54 reads (22%) | catalogued as COSV99698948; called by muse, mutect2, varscan2
- SPAG9 | c.1804G>T p.D602Y (on ENST00000262013 / NM_001130528.3; = p.D588Y on NM_003971.6) | Missense Mutation (SNP) | VAF 23/120 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.629); catalogued as rs1233133539, COSV56235288; called by muse, mutect2, varscan2
- SPATA19 | c.357G>C p.W119C | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100141292, COSV54483283; called by mutect2, varscan2
- SPATA31D1 | c.3473G>A p.R1158K | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT tolerated (0.66); PolyPhen benign (0.037); catalogued as COSV100782924, COSV61195588; called by muse, mutect2, varscan2
- SPATA31D1 | c.3474G>T p.R1158S | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT tolerated (0.67); PolyPhen benign (0.001); catalogued as COSV61195602; called by muse, mutect2, varscan2
- SPHK1 | c.256G>A p.E86K (on ENST00000392496 / NM_001355139.2; = p.E100K on NM_021972.4) | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs1228394330, COSV100039530; called by muse, mutect2
- SPHK2 | c.980C>T p.S327F | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as rs747521041, COSV55337306; called by muse, mutect2, varscan2
- SPINK5 | c.637G>A p.E213K | Missense Mutation (SNP) | VAF 15/29 reads (52%) | SIFT tolerated (0.13); PolyPhen benign (0.012); catalogued as COSV104372872, COSV56253697; called by muse, mutect2, varscan2
- SPTB | c.2384G>A p.S795N | Missense Mutation (SNP) | VAF 8/79 reads (10%) | SIFT tolerated (0.33); PolyPhen benign (0.006); catalogued as COSV67631700; called by muse, mutect2, varscan2
- ST6GALNAC1 | c.694C>T p.Q232* | Nonsense Mutation (SNP) | VAF 12/62 reads (19%) | catalogued as COSV99336625; called by muse, mutect2, varscan2
- STAB1 | c.6340A>G p.M2114V | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs1392203352; called by muse, mutect2
- STAM2 | c.677G>T p.G226V | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1418689397, COSV55731179; called by muse, mutect2
- STAM2 | c.676G>T p.G226C | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1180011909, COSV55731187; called by muse, mutect2, varscan2
- STAU2 | c.1432G>A p.E478K (on ENST00000524300 / NM_001164380.2; = p.E446K on NM_014393.2) | Missense Mutation (SNP) | VAF 16/110 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.766); catalogued as COSV63307980; called by muse, mutect2, varscan2
- SYNE1 | c.7951G>A p.E2651K (on ENST00000367255 / NM_182961.4; = p.E2658K on NM_033071.3) | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT tolerated (0.15); PolyPhen benign (0.11); catalogued as rs147040672; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TARS1 | c.1482T>G p.F494L | Missense Mutation (SNP) | VAF 34/86 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.06); catalogued as COSV54309132; called by muse, mutect2, varscan2
- TARS2 | c.112C>G p.L38V | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.054); catalogued as COSV64695363; called by muse, mutect2, varscan2
- TARS2 | c.344C>G p.S115C | Missense Mutation (SNP) | VAF 24/133 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as rs1414869796, COSV64695372; called by muse, mutect2, varscan2
- TASOR2 | c.3856C>G p.L1286V | Missense Mutation (SNP) | VAF 56/226 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1470468761, COSV60167381, COSV60167408; called by muse, mutect2, varscan2
- TBK1 | c.1915G>C p.D639H | Missense Mutation (SNP) | VAF 39/113 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.191); catalogued as rs778577820, COSV59155045; called by muse, mutect2, varscan2
- TEP1 | c.6662G>T p.R2221L | Missense Mutation (SNP) | VAF 21/36 reads (58%) | SIFT tolerated (0.09); PolyPhen benign (0.415); catalogued as rs146330073, COSV52992287; called by muse, mutect2, varscan2
- THAP11 | c.787G>A p.E263K | Missense Mutation (SNP) | VAF 31/133 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV54645990; called by muse, mutect2, varscan2
- THSD7B | c.2176A>T p.T726S | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.854); catalogued as COSV55684243; called by muse, mutect2, varscan2
- TJP1 | c.2266G>T p.E756* | Nonsense Mutation (SNP) | VAF 17/76 reads (22%) | catalogued as COSV100633126; called by muse, mutect2, varscan2
- TLR5 | c.112C>G p.L38V | Missense Mutation (SNP) | VAF 18/35 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.751); catalogued as COSV60558967; called by muse, mutect2, varscan2
- TMEM74 | c.422G>T p.W141L | Missense Mutation (SNP) | VAF 14/107 reads (13%) | SIFT tolerated (0.72); PolyPhen benign (0.415); catalogued as COSV52463243; called by muse, mutect2, varscan2
- TMEM74 | c.421T>C p.W141R | Missense Mutation (SNP) | VAF 14/112 reads (13%) | SIFT tolerated (0.5); PolyPhen benign (0.011); catalogued as COSV52463253; called by muse, mutect2, varscan2
- TMPRSS11F | c.29A>T p.E10V | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.047); catalogued as rs748540773, COSV62466366; called by muse, mutect2, varscan2
- TNP1 | c.14G>T p.R5L | Missense Mutation (SNP) | VAF 28/59 reads (47%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.817); catalogued as COSV52696673; called by muse, mutect2, varscan2
- TPRKB | c.271G>T p.E91* | Nonsense Mutation (SNP) | VAF 12/101 reads (12%) | catalogued as COSV99721831; called by muse, mutect2, varscan2
- TRA2B | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 12/43 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.107); catalogued as COSV60747160, COSV60747538; called by muse, mutect2, varscan2
- TRAF3IP3 | c.549C>T p.T183= | Splice Region (SNP) | VAF 16/63 reads (25%) | catalogued as rs750440768, COSV50552794; called by muse, mutect2, varscan2
- TRHR | c.280G>T p.G94C | Missense Mutation (SNP) | VAF 16/186 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61234115; called by muse, mutect2
- TRHR | c.281G>T p.G94V | Missense Mutation (SNP) | VAF 16/186 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61234124, COSV61234973; called by muse, mutect2
- TRPM3 | c.1924G>T p.E642* (on ENST00000357533 / NM_001366142.2; = p.E485* on NM_020952.6) | Nonsense Mutation (SNP) | VAF 56/117 reads (48%) | catalogued as COSV100678607; called by muse, mutect2, varscan2
- TTLL5 | c.3577G>T p.G1193C | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.871); catalogued as COSV54033361, COSV54042286; called by mutect2, varscan2
- TTLL5 | c.3578G>T p.G1193V | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.554); catalogued as COSV54033372; called by muse, mutect2, varscan2
- TUBA3C | c.1207G>A p.A403T | Missense Mutation (SNP) | VAF 30/150 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.053); catalogued as COSV68028336; called by muse, mutect2, varscan2
- UBLCP1 | c.826C>G p.L276V | Missense Mutation (SNP) | VAF 13/112 reads (12%) | SIFT tolerated (0.52); PolyPhen benign (0.007); catalogued as COSV57143285; called by muse, mutect2, varscan2
- UFC1 | c.424-2A>T p.X142_splice | Splice Site (SNP) | VAF 18/78 reads (23%) | catalogued as COSV57088555; called by muse, mutect2, varscan2
- VIRMA | c.4789G>A p.E1597K | Missense Mutation (SNP) | VAF 18/130 reads (14%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.987); catalogued as COSV52584852; called by muse, mutect2, varscan2
- VRTN | c.319C>G p.R107G | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.013); catalogued as COSV56440957, COSV56444142, COSV99832434; called by muse, mutect2, varscan2
- WDR44 | c.1933C>G p.Q645E | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV54163276; called by muse, mutect2, varscan2
- WDR93 | c.1364G>A p.G455E | Missense Mutation (SNP) | VAF 25/84 reads (30%) | SIFT tolerated (0.59); PolyPhen benign (0.066); catalogued as COSV51532178, COSV51535135; called by muse, mutect2, varscan2
- XAGE3 | c.223C>G p.Q75E | Missense Mutation (SNP) | VAF 70/84 reads (83%) | SIFT tolerated (0.43); PolyPhen benign (0.166); catalogued as COSV60569197; called by muse, mutect2, varscan2
- XIRP2 | c.5309del p.I1770Kfs*8 (on ENST00000628543; = p.I1945Kfs*8 on NM_152381.6) | Frame Shift Del (DEL) | VAF 7/38 reads (18%) | catalogued as COSV54699069; called by mutect2, pindel, varscan2
- XPO5 | c.1987G>T p.E663* | Nonsense Mutation (SNP) | VAF 29/92 reads (32%) | catalogued as COSV54830134, COSV99541387; called by muse, mutect2, varscan2
- ZFP36L2 | c.655G>T p.D219Y | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.671); catalogued as COSV56698024; called by muse, mutect2, varscan2
- ZFYVE9 | c.603G>T p.E201D | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.011); catalogued as COSV55093676; called by muse, mutect2, varscan2
- ZNF250 | c.1537G>A p.G513R | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs778619065, COSV52969186; called by muse, mutect2, varscan2
- ZNF292 | c.8002A>T p.I2668F | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.523); catalogued as COSV60539273; called by muse, mutect2, varscan2
- ZNF436 | c.1378G>C p.A460P | Missense Mutation (SNP) | VAF 25/96 reads (26%) | SIFT tolerated (0.28); PolyPhen benign (0.303); catalogued as COSV58358499; called by muse, mutect2, varscan2
- ZNF443 | c.1169A>G p.E390G | Missense Mutation (SNP) | VAF 36/224 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.916); catalogued as COSV56891644; called by muse, mutect2, varscan2
- ZNF710 | c.1522C>T p.R508W | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51563024; called by muse, mutect2, varscan2
- ZNF800 | c.793G>A p.E265K | Missense Mutation (SNP) | VAF 24/126 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV56175549; called by muse, mutect2, varscan2
- ZNF823 | c.1748A>G p.Y583C | Missense Mutation (SNP) | VAF 25/87 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.929); catalogued as COSV57873773; called by muse, mutect2, varscan2
- ZSCAN20 | c.1736G>T p.G579V | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.276); catalogued as COSV63682619; called by muse, mutect2, varscan2
- ACACA | c.4214G>T p.R1405L | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.758); called by muse, mutect2, varscan2
- EPHB3 | c.1897del p.V633Sfs*6 | Frame Shift Del (DEL) | VAF 8/52 reads (15%) | called by mutect2, pindel, varscan2
- FAM20B | c.17_19dup p.R6_V7insG | In Frame Ins (INS) | VAF 9/39 reads (23%) | called by mutect2, pindel, varscan2
- FBH1 | c.1020+2del p.X340_splice (on ENST00000362091 / NM_178150.3; = p.X391_splice on NM_032807.4) | Splice Site (DEL) | VAF 11/74 reads (15%) | called by mutect2, pindel, varscan2
- GTF2IRD2 | c.1908G>C p.K636N | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); called by muse, varscan2
- IGKV1-16 | c.256G>C p.G86R | Missense Mutation (SNP) | VAF 35/199 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- POTEE | c.2137G>T p.G713C | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- PRAMEF5 | c.326G>A p.C109Y | Missense Mutation (SNP) | VAF 27/177 reads (15%) | SIFT tolerated (0.21); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- RBM26 | c.1177del p.D393Mfs*14 | Frame Shift Del (DEL) | VAF 10/45 reads (22%) | called by mutect2, pindel*, varscan2
- SMAD6 | c.1394G>T p.R465L | Missense Mutation (SNP) | VAF 2/14 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- THSD7A | c.2806del p.S936Vfs*15 | Frame Shift Del (DEL) | VAF 35/124 reads (28%) | called by mutect2, pindel, varscan2
- ADGRG1 | c.868C>T p.L290= | Silent (SNP) | VAF 8/34 reads (24%) | catalogued as COSV65635623; called by muse, mutect2, varscan2
- AGTR1 | c.258C>T p.V86= | Silent (SNP) | VAF 9/56 reads (16%) | catalogued as rs1332854987, COSV62558118; called by muse, mutect2, varscan2
- AKAP13 | c.5983C>A p.R1995= (on ENST00000394518 / NM_007200.5; = p.R1999= on NM_006738.6) | Silent (SNP) | VAF 7/57 reads (12%) | catalogued as COSV63452897, COSV63456512; called by muse, mutect2, varscan2
- C11orf42 | c.313C>A p.R105= | Silent (SNP) | VAF 9/31 reads (29%) | catalogued as COSV56409884, COSV56411333; called by muse, mutect2, varscan2
- CD93 | c.1596C>G p.L532= | Silent (SNP) | VAF 29/68 reads (43%) | catalogued as COSV55665080; called by muse, mutect2, varscan2
- CDC42EP3 | c.303G>A p.P101= | Silent (SNP) | VAF 27/80 reads (34%) | catalogued as rs746119771, COSV54874086, COSV54874517; called by muse, mutect2, varscan2
- CHRNB3 | c.1068C>T p.Y356= | Silent (SNP) | VAF 10/51 reads (20%) | catalogued as COSV51494976; called by muse, mutect2, varscan2
- COL22A1 | c.2553T>C p.P851= | Silent (SNP) | VAF 13/39 reads (33%) | catalogued as COSV57336028; called by muse, mutect2, varscan2
- COL5A3 | c.3958C>A p.R1320= | Silent (SNP) | VAF 14/96 reads (15%) | catalogued as COSV53410396, COSV99070406; called by muse, mutect2, varscan2
- COP1 | c.1689C>T p.F563= | Silent (SNP) | VAF 14/50 reads (28%) | catalogued as rs973728540, COSV58166904; called by muse, mutect2, varscan2
- CREBBP | c.291G>A p.Q97= | Silent (SNP) | VAF 4/42 reads (10%) | catalogued as COSV99271747; called by muse, mutect2
- CYSLTR1 | c.847C>T p.L283= | Silent (SNP) | VAF 15/51 reads (29%) | catalogued as COSV64820096; called by muse, mutect2, varscan2
- DDAH2 | c.483C>T p.V161= | Silent (SNP) | VAF 4/50 reads (8%) | catalogued as rs777049602, COSV101007552; called by muse, mutect2
- DIP2B | c.2091C>G p.L697= | Silent (SNP) | VAF 20/79 reads (25%) | catalogued as COSV56583562; called by muse, mutect2, varscan2
- ERBB2 | c.1428C>T p.F476= | Silent (SNP) | VAF 4/26 reads (15%) | catalogued as rs532023577, COSV54070251; called by muse, mutect2
- FAS | c.21C>T p.L7= | Silent (SNP) | VAF 9/30 reads (30%) | catalogued as rs1312703118, COSV58238657; called by muse, mutect2, varscan2
- FBN2 | c.3105C>T p.T1035= | Silent (SNP) | VAF 20/50 reads (40%) | catalogued as rs760855981, COSV52497509, COSV52512059; called by muse, varscan2
- FZD8 | c.1587G>A p.L529= | Silent (SNP) | VAF 9/23 reads (39%) | catalogued as COSV65967880; called by muse, mutect2, varscan2
- GABARAP | c.120G>C p.R40= | Silent (SNP) | VAF 39/123 reads (32%) | catalogued as COSV56641931; called by muse, mutect2, varscan2
- GABRB3 | c.423C>A p.I141= | Silent (SNP) | VAF 20/65 reads (31%) | catalogued as COSV100160846, COSV54663408; called by muse, mutect2, varscan2
- H2AC14 | c.306C>G p.T102= | Silent (SNP) | VAF 27/125 reads (22%) | catalogued as COSV60797661; called by muse, mutect2, varscan2
- IFT88 | c.42G>T p.V14= (on ENST00000319980 / NM_001318493.2; = p.V5= on NM_006531.5 and 9 other RefSeq transcripts) | Silent (SNP) | VAF 15/47 reads (32%) | catalogued as rs775463707, COSV60673190; called by muse, mutect2, varscan2
- IGHG2 | c.213G>A p.V71= | Silent (SNP) | VAF 34/75 reads (45%) | called by muse, mutect2, varscan2
- IL20RA | c.624G>T p.L208= | Silent (SNP) | VAF 15/37 reads (41%) | catalogued as COSV57358180; called by muse, mutect2, varscan2
- INTS10 | c.942C>T p.T314= | Silent (SNP) | VAF 14/55 reads (25%) | catalogued as COSV67604165; called by muse, mutect2, varscan2
- KCNB1 | c.978G>A p.R326= | Silent (SNP) | VAF 11/52 reads (21%) | catalogued as COSV65568144; called by muse, mutect2, varscan2
- KIF18A | c.1323G>A p.L441= | Silent (SNP) | VAF 29/364 reads (8%) | catalogued as COSV54181331, COSV54183271; called by muse, mutect2
- KIR2DL1 | c.477T>C p.H159= | Silent (SNP) | VAF 27/48 reads (56%) | catalogued as rs1343836430, COSV52409571; called by muse, mutect2, varscan2
- LMAN1L | c.1464C>T p.N488= | Silent (SNP) | VAF 39/160 reads (24%) | catalogued as rs1567226131, COSV59001909; called by muse, mutect2, varscan2
- LMAN2 | c.201C>A p.V67= | Silent (SNP) | VAF 13/39 reads (33%) | catalogued as COSV57424585; called by muse, mutect2, varscan2
- LMOD2 | c.759C>T p.D253= | Silent (SNP) | VAF 5/32 reads (16%) | catalogued as rs746530747, COSV71755619; called by muse, mutect2, varscan2
- MLH3 | c.3117G>A p.T1039= | Silent (SNP) | VAF 23/97 reads (24%) | catalogued as rs752980464, COSV53154927; called by muse, mutect2, varscan2
- MRI1 | c.999C>T p.I333= (on ENST00000040663 / NM_001031727.4; = p.I286= on NM_032285.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 13/56 reads (23%) | catalogued as COSV50004340; called by muse, mutect2, varscan2
- MTUS2 | c.516G>A p.L172= | Silent (SNP) | VAF 10/63 reads (16%) | catalogued as COSV70916723; called by muse, mutect2, varscan2
- MUC5B | c.2910C>A p.T970= | Silent (SNP) | VAF 6/27 reads (22%) | catalogued as rs374061572; called by muse, mutect2, varscan2
- MYH11 | c.2958G>A p.E986= | Silent (SNP) | VAF 48/86 reads (56%) | catalogued as COSV55552603; called by muse, mutect2, varscan2
- MYO18B | c.6357C>A p.S2119= | Silent (SNP) | VAF 7/39 reads (18%) | catalogued as COSV59133911; called by muse, mutect2, varscan2
- NAT10 | c.705G>C p.L235= | Silent (SNP) | VAF 85/96 reads (89%) | catalogued as COSV57663724; called by muse, mutect2, varscan2
- NCKAP5 | c.3090C>T p.T1030= | Silent (SNP) | VAF 6/26 reads (23%) | catalogued as rs550917430, COSV58442597; called by muse, mutect2, varscan2
- NEDD4 | c.3105T>C p.Y1035= (on ENST00000508342 / NM_001284338.1; = p.Y616= on NM_006154.4) | Silent (SNP) | VAF 55/124 reads (44%) | catalogued as rs1283126369, COSV59061587; called by muse, mutect2, varscan2
- NLRP12 | c.1723C>T p.L575= | Silent (SNP) | VAF 22/59 reads (37%) | catalogued as rs1443243829, COSV60747226; called by muse, mutect2, varscan2
- NLRP3 | c.162G>T p.T54= | Silent (SNP) | VAF 7/16 reads (44%) | catalogued as rs769297212, COSV100276389, COSV60224016; called by muse, mutect2, varscan2
- OR13C5 | c.216C>T p.C72= | Silent (SNP) | VAF 10/60 reads (17%) | catalogued as COSV101053165; called by muse, mutect2, varscan2
- PARVG | c.339G>A p.V113= | Silent (SNP) | VAF 8/26 reads (31%) | catalogued as COSV63561796; called by muse, mutect2, varscan2
- PGM5 | c.1419G>T p.V473= | Silent (SNP) | VAF 8/69 reads (12%) | catalogued as COSV67167598; called by muse, mutect2, varscan2
- PNMA8B | c.1476C>T p.A492= | Silent (SNP) | VAF 8/67 reads (12%) | catalogued as rs1285616311, COSV66537685; called by muse, mutect2, varscan2
- PRKCQ | c.1299C>A p.S433= | Silent (SNP) | VAF 7/70 reads (10%) | catalogued as COSV54110879, COSV54120828; called by muse, mutect2, varscan2
- PRR5 | c.720G>T p.S240= (on ENST00000336985 / NM_181333.4; = p.S231= on NM_015366.4) | Silent (SNP) | VAF 14/54 reads (26%) | catalogued as rs149767702, COSV50060139; called by muse, mutect2
- PTPRZ1 | c.1821T>C p.Y607= | Silent (SNP) | VAF 27/54 reads (50%) | catalogued as rs754475015, COSV66436158; called by muse, mutect2, varscan2
- PYGL | c.1944C>T p.N648= | Silent (SNP) | VAF 17/83 reads (20%) | catalogued as COSV53585788; called by muse, mutect2, varscan2
- PYM1 | c.291G>A p.R97= | Silent (SNP) | VAF 17/33 reads (52%) | catalogued as COSV56811983; called by muse, mutect2, varscan2
- RALGAPA2 | c.5166C>T p.S1722= | Silent (SNP) | VAF 10/56 reads (18%) | catalogued as rs1291453925, COSV52496986, COSV52510989; called by muse, mutect2, varscan2
- RARB | c.1192T>C p.L398= (on ENST00000383772 / NM_001290216.2; = p.L391= on NM_000965.5 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 19/62 reads (31%) | catalogued as COSV51971969; called by muse, mutect2, varscan2
- RBP3 | c.597C>A p.I199= | Silent (SNP) | VAF 9/47 reads (19%) | called by muse, mutect2, varscan2
- RTN4R | c.657G>T p.P219= | Silent (SNP) | VAF 12/49 reads (24%) | catalogued as rs746556660, COSV50381207; called by muse, mutect2, varscan2
- SCNN1G | c.420G>T p.A140= | Silent (SNP) | VAF 30/113 reads (27%) | catalogued as COSV55598753, COSV55600203; called by muse, mutect2, varscan2
- SLC29A2 | c.1095C>T p.V365= | Silent (SNP) | VAF 10/23 reads (43%) | catalogued as COSV100237203; called by muse, mutect2, varscan2
- SLC35C1 | c.255G>T p.T85= | Silent (SNP) | VAF 13/30 reads (43%) | catalogued as rs374975158, COSV58479929; called by muse, mutect2, varscan2
- SLX4IP | c.51G>A p.V17= | Silent (SNP) | VAF 8/69 reads (12%) | catalogued as COSV57946595; called by muse, mutect2, varscan2
- SMAD6 | c.1392C>T p.V464= | Silent (SNP) | VAF 2/14 reads (14%) | called by muse, mutect2
- SMG1 | c.5586G>T p.V1862= | Silent (SNP) | VAF 5/20 reads (25%) | catalogued as COSV67171204; called by muse, mutect2, varscan2
- SPATA31A3 | c.2853A>G p.T951= | Silent (SNP) | VAF 8/18 reads (44%) | called by mutect2, varscan2
- SPRED1 | c.1314G>C p.G438= | Silent (SNP) | VAF 12/48 reads (25%) | catalogued as COSV54436067; called by muse, mutect2, varscan2
- SPTA1 | c.5526T>A p.A1842= | Silent (SNP) | VAF 36/118 reads (31%) | catalogued as rs1237472631, COSV63752779; called by muse, mutect2, varscan2
- ST7 | c.339C>A p.S113= | Silent (SNP) | VAF 25/116 reads (22%) | catalogued as COSV55384535; called by muse, mutect2, varscan2
- TBC1D32 | c.1899T>C p.Y633= | Silent (SNP) | VAF 17/31 reads (55%) | catalogued as rs920447894, COSV51542903; called by muse, mutect2, varscan2
- TCF7L2 | c.603G>T p.T201= (on ENST00000355995 / NM_001367943.1; = p.T178= on NM_030756.5) | Silent (SNP) | VAF 7/40 reads (18%) | catalogued as COSV53340546, COSV53340588; called by muse, mutect2, varscan2
- TMEM70 | c.48C>T p.L16= | Silent (SNP) | VAF 3/20 reads (15%) | catalogued as rs1246053882, COSV99514093; called by muse, mutect2
- TMTC1 | c.385C>T p.L129= (on ENST00000539277 / NM_001193451.2; = p.L21= on NM_175861.3) | Silent (SNP) | VAF 14/40 reads (35%) | catalogued as COSV55480965; called by muse, mutect2, varscan2
- TRAV9-2 | c.36C>G p.L12= | Silent (SNP) | VAF 9/37 reads (24%) | catalogued as rs1358748375; called by muse, mutect2, varscan2
- TTC32 | c.96C>A p.S32= | Silent (SNP) | VAF 8/47 reads (17%) | catalogued as COSV100367830, COSV61268125; called by muse, mutect2
- UBE4B | c.1068C>T p.L356= | Silent (SNP) | VAF 13/60 reads (22%) | catalogued as rs758645417, COSV53531997; called by muse, mutect2, varscan2
- XIRP2 | c.91C>A p.R31= (on ENST00000628543; = p.R206= on NM_152381.6) | Silent (SNP) | VAF 11/104 reads (11%) | catalogued as COSV54699057, COSV54700656; called by muse, mutect2, varscan2
- YTHDF3 | c.1524C>G p.V508= | Silent (SNP) | VAF 7/45 reads (16%) | catalogued as rs376889574, COSV101572420; called by muse, mutect2
- ZFP36L2 | c.654G>T p.A218= | Silent (SNP) | VAF 5/14 reads (36%) | catalogued as rs773065054, COSV56698029; called by muse, mutect2, varscan2
- ZNF749 | c.876C>T p.L292= | Silent (SNP) | VAF 19/72 reads (26%) | catalogued as rs1271651491, COSV61946063; called by muse, mutect2, varscan2
- ZNF780B | c.1224G>A p.Q408= | Silent (SNP) | VAF 59/137 reads (43%) | catalogued as COSV55464039; called by muse, mutect2, varscan2
- AC024598.1 | c.1130-1028C>G | Intron (SNP) | VAF 11/27 reads (41%) | catalogued as rs79964532, COSV100760463, COSV60823681; called by muse, mutect2, varscan2
- DCHS2 | n.7587A>C | RNA (SNP) | VAF 13/34 reads (38%) | catalogued as COSV61771765; called by muse, mutect2, varscan2
- DST | c.4296+4707G>T | Intron (SNP) | VAF 16/76 reads (21%) | catalogued as COSV55013566; called by muse, mutect2, varscan2
- EIF4A2 | c.208+122T>A | Intron (SNP) | VAF 32/90 reads (36%) | catalogued as COSV100125627; called by muse, mutect2, varscan2
- GPRC5A | c.*3305G>A | 3'UTR (SNP) | VAF 9/32 reads (28%) | catalogued as COSV99185628; called by muse, mutect2, varscan2
- HNF4G | c.-23-3800A>G | Intron (SNP) | VAF 16/113 reads (14%) | catalogued as COSV62968379; called by muse, mutect2, varscan2
- KCNU1 | c.2010-17164G>A | Intron (SNP) | VAF 6/35 reads (17%) | catalogued as rs1185315352; called by muse, mutect2
- KCNU1 | c.2010-17058G>T | Intron (SNP) | VAF 6/48 reads (13%) | called by muse, mutect2, varscan2
- PTER | c.*1G>A | 3'UTR (SNP) | VAF 10/50 reads (20%) | catalogued as COSV100126680, COSV100126831; called by muse, mutect2, varscan2
- SLC5A3 | c.-2G>C | 5'UTR (SNP) | VAF 15/86 reads (17%) | catalogued as rs949179876, COSV100758063; called by muse, mutect2, varscan2
